Somatic mutation profile of tumor specimen TCGA-F4-6704-01A (aliquot TCGA-F4-6704-01A-11D-1835-10) from TCGA case TCGA-F4-6704, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 60.1 years (21,949 days).
Specimen TCGA-F4-6704-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 037cbd7d-8cd9-433f-ba15-b8e121624c4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6704-11A (Solid Tissue Normal), aliquot TCGA-F4-6704-11A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b9d67fe-99fb-4741-8d7b-04a993823125

The open-access MAF lists 65 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 11, Nonsense Mutation 3, RNA 1, Frame Shift Ins 1, 5'Flank 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTA1 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV64203840; called by muse, mutect2, varscan2
- ADAP2 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766262485, COSV100437089; called by muse, mutect2, varscan2
- ANKS3 | c.619A>C p.M207L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as COSV100422804; called by muse, mutect2
- ARL8B | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747994602, COSV56578900; called by muse, mutect2, varscan2
- ATAD2 | c.1570C>T p.R524C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778430144, COSV54880549; called by mutect2, varscan2
- BICD2 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs755525474, COSV100794021; called by mutect2, varscan2
- BSN | c.11710G>A p.A3904T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1259659096; called by muse, mutect2
- CA9 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.025); catalogued as COSV61407201; called by mutect2, varscan2
- CAMLG | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as rs748338400, COSV51804821; called by muse, mutect2, varscan2
- CARD11 | c.2006C>T p.T669M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.186); catalogued as rs186255478, COSV62756504; called by mutect2, varscan2
- CDH9 | c.1244A>C p.N415T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV99141115; called by muse, mutect2, varscan2
- CGAS | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as rs190867294, COSV64807915; called by muse, mutect2, varscan2
- CHRNG | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as rs752487562, COSV101263879; called by muse, mutect2, varscan2
- CNTN2 | c.1603G>A p.D535N | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959574033, COSV59347981; called by muse, mutect2, varscan2
- DCBLD1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV99756847; called by muse, mutect2, varscan2
- DICER1 | c.2054G>A p.S685N | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100601602; called by muse, mutect2
- ELAPOR1 | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100884597; called by muse, mutect2, varscan2
- F13B | c.991C>A p.Q331K | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100803128; called by muse, mutect2, varscan2
- FAM217B | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV100674324; called by muse, mutect2
- FCGRT | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as COSV54543846; called by muse, mutect2, varscan2
- GRIA2 | c.1592C>A p.S531Y | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52388580, COSV52400410; called by muse, mutect2, varscan2
- IGF2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100323815; called by muse, mutect2, varscan2
- IL6 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51732665; called by muse, mutect2, varscan2
- INO80D | c.1867G>C p.D623H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68959684; called by muse, mutect2, varscan2
- IQGAP2 | c.2810A>T p.K937M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs1253259229, COSV57182827, COSV99166611; called by muse, mutect2, varscan2
- JARID2 | c.2947G>A p.V983I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.8); PolyPhen benign (0.203); catalogued as rs751270951, COSV59194731; called by muse, mutect2, varscan2
- LILRA2 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as rs774578964, COSV52195113, COSV52195931; called by muse, varscan2
- MED14 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs1034557473, COSV61357885; called by muse, mutect2, varscan2
- MED26 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54662020; called by muse, varscan2
- MXRA5 | c.6098C>T p.A2033V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99475293; called by mutect2, varscan2
- NCKAP1L | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.242); catalogued as rs991377942, COSV99514210; called by muse, mutect2
- NFASC | c.2501G>A p.R834Q (on ENST00000339876 / NM_001378329.1; = p.R937Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.107); catalogued as rs375472837; called by muse, mutect2, varscan2
- OR52L1 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs763535932, COSV59989257; called by mutect2, varscan2
- PABPC1L | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747061139, COSV99407387; called by muse, mutect2, varscan2
- PCDH11Y | c.3554C>T p.T1185I | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV53087581; called by muse, mutect2, varscan2
- PRCC | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54857601; called by muse, mutect2
- PTCHD4 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as rs773331588, COSV59792366; called by muse, mutect2, varscan2
- PTEN | c.193T>G p.Y65D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587780005, COSV64297052, COSV64299797; called by muse, mutect2, varscan2
- PZP | c.2201C>A p.P734H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.396); catalogued as COSV99735422; called by muse, mutect2, varscan2
- SERPINB1 | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as COSV66313846; called by mutect2, varscan2
- SLC16A13 | c.71C>A p.S24* | Nonsense Mutation (SNP) | VAF 15/190 reads (8%) | catalogued as COSV100340060; called by muse, mutect2
- SLC1A7 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776329055, COSV100439411, COSV57016224; called by mutect2, varscan2
- SMARCA1 | c.2492A>G p.E831G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV100946265; called by mutect2, varscan2
- TECTA | c.4171G>A p.A1391T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.335); catalogued as rs779748263, COSV50764352; called by muse, mutect2, varscan2
- TIE1 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.75); PolyPhen benign (0.067); catalogued as rs781750183, COSV65250778; called by muse, mutect2, varscan2
- TMEM207 | c.326C>G p.P109R | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV61562102; called by muse, mutect2
- TPP2 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as rs764842046, COSV65754097; called by muse, mutect2, varscan2
- USH2A | c.2426A>T p.N809I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV56410015; called by muse, mutect2, varscan2
- CCL16 | c.320T>A p.I107N | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- DSP | c.2359dup p.Y787Lfs*2 | Frame Shift Ins (INS) | VAF 9/53 reads (17%) | called by mutect2, varscan2
- C3 | c.4950C>T p.G1650= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs757774081, COSV55571624; called by muse, mutect2, varscan2
- COL5A1 | c.582C>T p.S194= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs563191799, COSV100879265; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGSF10 | c.2004G>A p.R668= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs745895078, COSV56789681; called by muse, mutect2, varscan2
- KCNA3 | c.393C>T p.G131= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs756473605, COSV100871177, COSV100871242; called by mutect2, varscan2
- MACROD1 | c.351G>A p.K117= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV55364848; called by muse, mutect2, varscan2
- MFN1 | c.615C>T p.V205= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as rs1026406505, COSV54941567; called by muse, mutect2, varscan2
- NLRC5 | c.5583G>A p.Q1861= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99346129; called by muse, mutect2, varscan2
- RFC5 | c.96T>C p.N32= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99969716; called by muse, mutect2, varscan2
- SCN9A | c.60T>A p.L20= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV57618846; called by muse, mutect2, varscan2
- TTN | c.6615G>A p.V2205= (on ENST00000591111; = p.V2159= on NM_003319.4) | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100588202; called by muse, mutect2, varscan2
- UGT3A2 | c.373T>C p.L125= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV99235866; called by muse, mutect2, varscan2
- ATG2A | chr11:64891417 G>A | 3'Flank (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- DCHS2 | n.2019G>A | RNA (SNP) | VAF 12/32 reads (38%) | catalogued as COSV59735237; called by muse, mutect2, varscan2
- DHRS4L1 | n.177-483T>A | Intron (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- ZNF22 | chr10:45000674 T>G | 5'Flank (SNP) | VAF 9/42 reads (21%) | catalogued as rs775838158, COSV100026471, COSV53584804; called by muse, mutect2, varscan2
